Somatic mutation profile of tumor specimen RC-B6E4-TBP1-B (aliquot RC-B6E4-TBP1-B-1-0-D-A93N-47) from RC case RC-B6E4, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants); Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.3 years (21,277 days).
Specimen RC-B6E4-TBP1-B: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 068d4eae-db36-4676-ba31-ed74173e13b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6E4-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B6E4-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a84acbd7-b571-4abc-93d2-eccf0237f639

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.12808T>G p.F4270V | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101291241; called by muse, mutect2, varscan2
- GLI2 | c.2810C>T p.A937V (on ENST00000361492 / NM_001374353.1; = p.A954V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs1258846094; called by muse, mutect2, varscan2
- TAL1 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs774469518, COSV53747554; called by muse, mutect2, varscan2
- ITSN1 | c.2882T>G p.F961C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRU | c.3775C>T p.P1259S | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF570 | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, varscan2
- DNAAF1 | c.873G>T p.A291= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs149704838; called by muse, mutect2, varscan2
- EPB41L2 | c.1584C>T p.A528= | Silent (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.885G>A p.E295= | Silent (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2, varscan2
- IRX2 | c.1158G>A p.S386= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs1288354493, COSV57409904; called by mutect2, varscan2
- TTC28 | c.1803C>A p.G601= | Silent (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2
- BDH1 | c.-43-9415C>T | Intron (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
